Somatic mutation profile of tumor specimen TCGA-L5-A4OO-01A (aliquot TCGA-L5-A4OO-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.0 years (27,757 days).
Specimen TCGA-L5-A4OO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4553f078-94ff-464d-af38-d816d0b6c3b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OO-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OO-11A-12D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1a178bd-7c94-47bc-946b-570f87e7d3ce

The open-access MAF lists 93 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Nonsense Mutation 4, Frame Shift Del 4, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS2 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs759648995; called by muse, mutect2, varscan2
- CAMK1G | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375301374; called by muse, mutect2, varscan2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2
- ERBB4 | c.1763A>G p.N588S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.284); catalogued as COSV53602832; called by muse, mutect2, varscan2
- FLG | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV64252176; called by muse, mutect2, varscan2
- GABRA4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV51929696; called by muse, mutect2, varscan2
- GOPC | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373946370; called by muse, mutect2, varscan2
- HECW1 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1339583851, COSV67829594; called by muse, mutect2, varscan2
- KCNA6 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs1202819313, COSV54974410; called by muse, mutect2, varscan2
- KRTAP13-1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374257240, COSV62664445; called by muse, mutect2, varscan2
- LRP2 | c.9128G>A p.R3043H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as rs143078432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC28 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs771064031, COSV57336612; called by muse, mutect2, varscan2
- MAMSTR | c.364G>A p.A122T (on ENST00000318083 / NM_001130915.2; = p.A19T on NM_182574.2) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1297931939; called by muse, mutect2, varscan2
- MAP3K10 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750540519, COSV53421779; called by muse, mutect2, varscan2
- MYH9 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs759107183, CM1310622; called by muse, mutect2, varscan2
- NAT8 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1558725966; called by muse, mutect2, varscan2
- OR2M7 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.923); catalogued as rs927762001; called by muse, mutect2, varscan2
- OSBPL6 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs149806664, COSV99507439; called by muse, mutect2, varscan2
- PCDH11X | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs754533820, COSV104403083; called by muse, mutect2, varscan2
- PCDHA6 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV65342079; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- PDCD10 | c.58A>G p.M20V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs138275885, CM135546; called by muse, mutect2, varscan2
- PPP2R1A | c.1723G>A p.V575I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1158328586; called by muse, mutect2, varscan2
- PRDM15 | c.3268G>A p.V1090M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs1165875283, COSV99521147; called by muse, mutect2, varscan2
- PSG9 | c.973A>T p.I325F | Missense Mutation (SNP) | VAF 70/288 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs140571643; called by muse, mutect2
- RPUSD2 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140454770, COSV59766232; called by muse, mutect2, varscan2
- RTN4R | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.075); catalogued as COSV50380782; called by mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- SEC24D | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as rs761516204; called by muse, mutect2, varscan2
- SLC2A14 | c.667A>T p.S223C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs886440679; called by muse, mutect2, varscan2
- SNX11 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs774783427, COSV63658942; called by muse, mutect2, varscan2
- SPTA1 | c.2753A>C p.K918T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63761644; called by muse, mutect2, varscan2
- TBC1D8 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777127877; called by muse, mutect2, varscan2
- TFPI2 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV55989930, COSV55990186; called by muse, mutect2, varscan2
- TTN | c.5255G>A p.R1752H (on ENST00000591111; = p.R1706H on NM_003319.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs150737838, COSV59901601; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USHBP1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1173108934; called by muse, mutect2, varscan2
- ADGRV1 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ASTE1 | c.1642T>C p.C548R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ATP2A2 | c.1729C>T p.L577F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- C20orf85 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- CDH5 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CDKN2D | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DDX60L | c.1568A>T p.Y523F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ELP5 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.89); called by muse, mutect2
- ENTPD2 | c.332_333del p.R111Tfs*42 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- FAM193A | c.1431T>G p.Y477* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- FOLR3 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- FSTL4 | c.1487del p.N496Mfs*26 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- GRB14 | c.1367A>G p.Q456R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ITGA4 | c.449dup p.N150Kfs*8 | Frame Shift Ins (INS) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.2392C>A p.Q798K (on ENST00000286628 / NM_001161352.2; = p.Q740K on NM_002247.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- KIF6 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2A | c.8339T>C p.M2780T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRT9 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MAPRE1 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MBTPS2 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MORC1 | c.2477+2T>A p.X826_splice | Splice Site (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- MPHOSPH8 | c.213+1del | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- NLRP11 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR4C12 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PSG1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2
- PTPN23 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- RAPGEFL1 | c.980_1002del p.Y327Ffs*25 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- SMAD9 | c.784T>G p.F262V (on ENST00000379826 / NM_001127217.3; = p.F225V on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SWT1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- TGM4 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC21A | c.3362C>A p.S1121Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- TTC7B | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZC3H18 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); called by muse, mutect2
- ADGRG1 | c.160C>T p.L54= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ALPK3 | c.4362C>T p.P1454= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1382646803; called by muse, mutect2, varscan2
- ARMC5 | c.2085G>A p.P695= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs369056576; called by muse, mutect2, varscan2
- CACNA1E | c.216C>T p.F72= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs1366077835, COSV100705145, COSV62392787; called by muse, mutect2, varscan2
- CBFA2T3 | c.1374C>T p.S458= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- DLX4 | c.360G>A p.P120= (on ENST00000240306 / NM_138281.3; = p.P48= on NM_001934.3) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV53591049; called by muse, mutect2, varscan2
- DNER | c.822C>T p.L274= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs779156111, COSV59171040; called by muse, mutect2, varscan2
- DPF3 | c.756G>A p.P252= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs374644462; called by muse, mutect2, varscan2
- FOXA2 | c.771C>T p.C257= (on ENST00000377115 / NM_153675.3; = p.C263= on NM_021784.5) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs774892375; called by muse, mutect2
- GPD2 | c.1593A>G p.P531= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs748864177; called by muse, mutect2, varscan2
- NCF1 | c.78C>T p.Y26= | Silent (SNP) | VAF 34/210 reads (16%) | called by muse, varscan2
- PCDH10 | c.48C>A p.V16= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1252572098, COSV52103006; called by muse, mutect2, varscan2
- PCDHA13 | c.1638C>A p.G546= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as COSV56530149; called by muse, varscan2
- PCNP | c.300A>G p.P100= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- RIBC2 | c.681C>T p.I227= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs768680462, COSV61581991; called by muse, mutect2, varscan2
- SELL | c.1065T>C p.V355= (on ENST00000650983; = p.V342= on NM_000655.5) | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- SHROOM2 | c.3288G>A p.T1096= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs374276560; called by muse, mutect2, varscan2
- SMC2 | c.145C>T p.L49= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- TBL1Y | c.774C>T p.F258= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs375467650, COSV60733094; called by muse, mutect2, varscan2
- ZNF677 | c.36T>C p.D12= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.939C>T p.I313= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- DCHS2 | n.3641A>G | RNA (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.-2G>T | 5'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- RAB4A | c.*1395C>G | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
